Gene-level copy-number profile of tumor specimen ALCH-B4FP-TTP1-A from ALCHEMIST case ALCH-B4FP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,968 days).
Specimen ALCH-B4FP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d69dbfad-0f73-4fb7-bbb0-6d32746a1aef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4FP-NB2-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/8ffc7913-ffe8-4a1d-9a8a-d9ebd4b616e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 264; copy number 1: 22,433; copy number 2: 27,937; copy number 3: 6,044; copy number 4: 1,767; copy number 5: 395; copy number 6: 3; copy number 7: 1; copy number 8: 17; copy number 9: 11; copy number 10: 1; copy number 12: 3; copy number 15: 1; copy number 17: 1; copy number 34: 1.

Homozygous deletions (total copy number 0; autosomes only): 151 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–2): AL627309.3.
- chr2:106,487,364–106,544,297, 1 gene (within-gene range 0–2): CD8B2.
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr9:65,189,995–65,230,861, 3 genes: BMS1P12, AL512605.1, AL512605.2.
- chr9:66,022,661–66,113,085, 5 genes (within-gene range 0–12): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–1): NEK6, AL162724.2, AL162724.1.
- chr9:127,934,503–127,940,952, 2 genes (within-gene range 0–1): AL157935.1, DPM2.
- chr10:14,986,942–14,987,515, 1 gene (within-gene range 0–1): OR7E110P.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr12:122,865,335–122,888,720, 2 genes (within-gene range 0–1): AC027290.1, AC027290.2.
- chr12:122,983,480–123,150,015, 4 genes: PITPNM2, MIR4304, PITPNM2-AS1, AC026362.2.
- chr13:112,894,378–113,099,742, 5 genes: MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3.
- chr13:113,667,219–113,751,089, 2 genes: GRK1, LINC00552.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–1): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–1): ADAMTS7.
- chr15:96,325,938–96,345,651, 3 genes (within-gene range 0–1): NR2F2, MIR1469, AC103746.1.
- chr17:17,167,946–17,185,554, 4 genes (within-gene range 0–1): AC055811.1, RNU6-767P, RN7SL775P, AC055811.4.
- chr17:39,603,536–39,636,626, 3 genes: NEUROD2, AC087491.1, PPP1R1B.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.
- chr17:61,361,668–61,485,110, 7 genes (within-gene range 0–1): AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1.
- chr17:79,018,131–79,088,599, 3 genes: C1QTNF1-AS1, C1QTNF1, ENGASE.
- chr17:81,703,371–81,721,016, 2 genes (within-gene range 0–1): AC139530.2, SLC25A10.
- chr18:37,473,330–37,473,977, 1 gene (within-gene range 0–2): AC129908.1.
- chr19:18,434,388–18,522,116, 5 genes (within-gene range 0–2): ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3.
- chr20:34,955,810–35,002,437, 3 genes (within-gene range 0–2): MYH7B, MIR499A, MIR499B.
- chr20:57,105,741–58,004,648, 26 genes: AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 433 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,632,568–2,636,620, 1 gene, copy number 6 (within-gene range 2–6): MMEL1-AS1.
- chr2:189,560,590–189,877,629, 11 genes, copy number 8: SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1.
- chr3:188,107,072–188,890,671, 6 genes, copy number 8: AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28.
- chr6:68,040,290–68,576,191, 5 genes, copy number 5: AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2.
- chr6:126,304,223–127,213,609, 1 gene, copy number 5 (within-gene range 4–5): AL356534.1.
- chr6:126,484,631–129,861,547, 43 genes, copy number 5: MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244.
- chr7:5,620,047–6,403,967, 24 genes, copy number 5: RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1.
- chr7:21,381,363–30,700,129, 201 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:74,773,962–74,789,376, 1 gene, copy number 15: NCF1.
- chr8:78,675,743–78,805,523, 1 gene, copy number 5 (within-gene range 3–5): IL7.
- chr8:78,760,142–81,284,777, 51 genes, copy number 5: THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr9:66,082,350–66,085,031, 2 genes, copy number 12: SNX18P4, AL513478.1.
- chr12:26,905,181–27,972,733, 35 genes, copy number 5: INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2.
- chr16:32,600,299–32,615,639, 1 gene, copy number 10: AC137800.1.
- chr19:29,205,320–30,228,715, 24 genes, copy number 5 (within-gene range 4–5): UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.
- chr20:32,170,390–32,439,319, 8 genes, copy number 5: RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1.
- chr21:32,913,649–33,071,104, 1 gene, copy number 9 (within-gene range 3–9): AP000282.1.
- chr21:33,025,935–33,310,187, 10 genes, copy number 9: OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB.
- chr21:43,053,191–43,141,092, 4 genes, copy number 5–34: CBS, U2AF1, MRPL51P2, FRGCA.
- chr21:43,414,483–43,427,131, 1 gene, copy number 17: SIK1.
- chr22:18,846,811–18,861,049, 1 gene, copy number 6 (within-gene range 2–6): AC008132.1.
- chr22:18,906,028–18,914,238, 1 gene, copy number 7 (within-gene range 2–7): DGCR6.

Autosomal genes at a single copy (total copy number 1): 20,020. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
